Gene-level copy-number profile of tumor specimen TCGA-RA-A741-01A from TCGA case TCGA-RA-A741, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 34.5 years (12,607 days).
Specimen TCGA-RA-A741-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6d2ffa68-2020-4d96-831d-b164f95cc439.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RA-A741-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c6f7877-b7eb-4e8f-bc19-b0113c95ea17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,449; copy number 2: 47,289; copy number 3: 3,169; copy number 4: 1,816; copy number 5: 41; copy number 9: 3; copy number 11: 28; copy number 16: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RA-A741-01A-11D-A33N-01): tumor purity 0.86, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 91 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:66,638,667–67,443,821, 38 genes, copy number 5: RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1, RPS6KB2, RPS6KB2-AS1, PTPRCAP, CORO1B.
- chr11:101,451,564–102,628,070, 25 genes, copy number 5–16: TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.
- chr18:24,725,762–26,091,217, 11 genes, copy number 11 (within-gene range 4–11): AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18.
- chr18:26,655,737–27,190,698, 1 gene, copy number 11 (within-gene range 4–11): AQP4-AS1.
- chr18:26,822,341–28,177,946, 16 genes, copy number 11 (within-gene range 1–11): AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1.

Autosomal genes at a single copy (total copy number 1): 7,449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
